TCGA case TCGA-DJ-A3V6 — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/76c4d298-6f17-4f11-a706-cd844a0e0914

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 54 years; Vital status: Alive.

Diagnoses (2)
1. Papillary carcinoma, columnar cell (the primary disease): ICD-O-3 morphology code: 8344/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 54.4 years (19,870 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: Yes; Residual disease: R0; Days to last follow up: 818 days (2.2 years); Tumor focality: Multifocal.
   Pathology details: Consistent pathology review: Yes; Extrathyroid extension: Minimal (T3); Measurement unit: Centimeters; Tumor depth measurement: 1; Tumor length measurement: 1.8; Tumor width measurement: 1.2.
   Treatment given: Treatment type: Radiation, Systemic; Days to treatment start: 223 days; Days to treatment end: 223 days; Treatment dose: 120 mCi; Treatment outcome: Complete Response; Number of fractions: 1; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Prescribed dose: 119.8; Prescribed dose units: mCi; Pretreatment: rhTSH; Timepoint category: First Treatment.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Treatment dose: 120 mCi; Pretreatment: rhTSH.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation, External Beam.
2. Malignant lymphoma, non-Hodgkin, NOS: ICD-O-3 morphology code: 9591/3; Classification of tumor: Prior primary; Age at diagnosis: 49.1 years (17,922 days); Days to diagnosis: -1,948 days (-5.3 years); AJCC staging edition: 6th; AJCC pathologic stage: Stage II.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cyclophosphamide + Doxorubicin + Prednisone + Rituximab + Vincristine; Regimen or line of therapy: R-CHOP; Days to treatment start: -1,891 days (-5.2 years); Treatment anatomic sites: Body, total.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.

Follow-up (4 entries)
- Days to follow up: 454 days (1.2 years); Disease response: Tumor Free.
- Days to follow up: 818 days (2.2 years); Disease response: Tumor Free.
- Imaging type: CT Scan; Imaging anatomic site: Lymph Node; Timepoint: Preoperative.
- Disease response: Complete Response; Timepoint: Within 3 Months of Surgery.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DJ-A3V6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 190 mg.
  Slide TCGA-DJ-A3V6-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DJ-A3V6-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DJ-A3V6-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: Yes; Tumor status: Tumor free; History radiation exposure: No; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Tall Cell (>= 50% tall cell features); Laterality: Left lobe; Lymph nodes preop imaging: Yes; Lymph nodes examined: No; Genotypic analysis detected: No; I 131 radiation first treatment method: rhTSH; I 131 radiation first treatment dose: 119.8 mCi; I 131 radiation treatment cumulative dose: 119.8 mCi; Radiation therapy xrt method prep: Patient Did Not Receive External Radiation Therapy; Clinical status within 3 mths surgery: No imaging evidence of disease; New tumor event diagnosis indicator: No.
- Neoplasm dimension: Tumor size width: 1.0.
- Lymph node preoperative assessment diagnostic imaging types: Lymph nodes preop imaging type: CT with contrast.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; I 131 radiation first treatment method: rhTSH; I 131 radiation first treatment dose: 119.8 mCi; I 131 radiation subsequent treatment: 0; I 131 radiation treatment cumulative dose: 119.8 mCi; Radiation therapy xrt method prep: Patient Did Not Receive External Radiation Therapy; Clinical status within 3 mths surgery: No imaging evidence of disease; New tumor event diagnosis indicator: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Lymphoma; Other malignancy histological type: Non-Hodgkin's lymphoma.
- Other malignancy form, Drug treatment: Pharmaceutical therapy extent: Systemic.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: Patient had a prior non-Hodgkins lymphoma that was treated with systemic chemotherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 818 days; disease-specific survival: no event (censored), 818 days; disease-free interval: no event (censored), 818 days; progression-free interval: no event (censored), 818 days.
